Surgical pathology report (de-identified scan), TCGA case TCGA-49-4490, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Johns Hopkins, specimen TCGA-49-4490-01A (Primary Tumor).

FINAL DIAGNOSIS ----- Pathologist [REDACTED]

1. ANTERIOR MEDIASTINAL LYMPH NODE (EXCISION): METASTATIC ADENOCARCINOMA IN ONE (1) LYMPH NODE WITH EXTENSION INTO PERINODAL SOFT TISSUE.
2. LEFT UPPER LOBE LUNG (PARTIAL PNEUMONECTOMY): MODERATE TO POORLY DIFFERENTIATED ADENOCARCINOMA. BRONCHIAL AND VASCULAR MARGINS OF RESECTION, NEGATIVE FOR TUMOR. EXTENSIVE LYMPHATIC INVASION. METASTATIC CARCINOMA IN ONE (1) LYMPH NODE.
3. AORTIC ARCH LYMPH NODE (EXCISION): METASTATIC POORLY DIFFERENTIATED CARCINOMA IN SOFT TISSUE.
- [REDACTED]
- [REDACTED]

Source: NCI Genomic Data Commons file 25044437-4832-4145-8dfd-26c5708b0857 (TCGA-49-4490.D6EC6F67-0C16-4396-BE41-AAA6868A6106.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).